Surgical pathology report (de-identified scan), TCGA case TCGA-10-0938, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0938-01A (Primary Tumor).

[page 1 of 2]
- [REDACTED]
- (A) RIGHT OVARY AND PORTION OF FALLOPIAN TUBE:
OVARY, HIGH-GRADE PAPILLARY SEROUS CARCINOMA.
THE TUMOR INVOLVES THE FALLOPIAN TUBE.
[REDACTED]
- (B) UTERUS, CERVIX, LEFT FALLOPIAN TUBE AND OVARY:
MINUTE FOCI OF PAPILLARY SEROUS CARCINOMA INVOLVING THE OVARY, PERIADNEXAL SOFT TISSUE AND FALLOPIAN TUBE LUMEN.
Hyperplastic endometrial polyp.
Simple endometrial hyperplasia without atypia and focal mucinous metaplasia.
Adenomyosis.
Uterine cervix, Nabothian cysts.
- (C) OMENTUM:
METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA.
- (D) ANTERIOR ABDOMINAL WALL:
METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA.
- [REDACTED]

GROSS DESCRIPTION

(A) RIGHT OVARY AND PORTION OF TUBE – An ovarian mass measuring 8.0 x 7.0 x 6.0 cm, fallopian tube measuring 5.0 x 1.0 cm and paraovarian soft tissue.

The tumor replaces the entire ovary and demonstrates papillary areas (occupying approximately 40%), solid tan-yellow areas (occupying 30%) and a cystic area with blood clot and smooth lining (30%). The tumor does not extend into the fallopian tube. No normal ovary is identified. Fallopian tube on serial sectioning is unremarkable.

SECTION CODE: A1, A2, section of ovary and tumor for frozen section; A3-A7, sections from the papillary areas; A8-A12, sections from the solid area; A13-A15, sections from the cyst with blood clot; A16, fallopian tube. [REDACTED]

FSDX: HIGH GRADE PAPILLARY SEROUS CARCINOMA. [REDACTED]

(B) UTERUS, CERVIX, LEFT TUBE AND OVARY – A 9.0 x 5.0 x 5.0 cm uterus with attached unremarkable left ovary 1.5 x 0.8 x 0.5 cm, and a portion of fallopian tube 2.5 cm in length x 0.5 cm in diameter.

Located within the fundus is a 2.5 x 1.5 x 1.0 cm, well-circumscribed, soft, friable, polypoid mass that involves the anterior and posterior endometrium. The polyp is cystic and very friable. The lesion is superficial and there is no identifiable extension to the myometrium. The polyp focally extends to the posterior lower uterine segment. The adjacent normal endometrium has a maximum thickness of 0.1 cm.

The myometrium is thin and unremarkable.

The left ovary is sclerotic with a white-tan cut surface. Multiple, small, paratubal cysts ranging in size from 0.2 to 0.3 cm are present attached to the surface of the tube. The fallopian tube is otherwise unremarkable.

INK CODE: Black-uterine serosa.

SECTION CODE: B1, cervix at 3 o'clock; B2, cervix at 9 o'clock; B3, anterior cervix; B4, B5, anterior lower uterine segment; B6-B13, endometrial polyp attached to the anterior endometrium and adjacent myometrium; B14-B15, polyp attached to the posterior endometrium; B16, B17 and B18, lower posterior uterine segment; B19-B22, representative sections of the endometrium; B23, B24, ovary; B25, paratubal cysts and left fallopian tube. [REDACTED]

[page 2 of 2]
[REDACTED]

(C) OMENTUM – A portion of omentum, 11.0 x 12.0 x 3.5 cm. The omentum is diffusely replaced by white-tan tumor tissue.

SECTION CODE: C1-C10, representative sections of omentum.

[REDACTED]

(D) ANTERIOR ABDOMINAL WALL – Portions of pink-tan soft tissue 4.0 x 3.0 x 0.5 cm and 2.5 x 1.7 x 0.5 cm. An ill-defined white-tan tumor is present in the larger portion of the specimen 1.0 x 0.7 x 0.7 cm. The cut surface of the second fragment is light tan.

SECTION CODE: D1, D2, nodule on large fragment; D3, representative sections of the small fragment.

[REDACTED]

CLINICAL HISTORY

History of ovarian carcinoma.

[REDACTED]

[REDACTED]

Start of ADDENDUM

Source: NCI Genomic Data Commons file f93bbe69-3092-44ec-b49e-5cdde4c97cb7 (TCGA-10-0938.FAA8920A-3B4A-4767-BDB1-5D086E51FE92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).